Surgical pathology report (de-identified scan), TCGA case TCGA-DB-A64Q, project TCGA-LGG (Brain Lower Grade Glioma), tissue source site Mayo Clinic - Rochester, specimen TCGA-DB-A64Q-01A (Primary Tumor).

[page 1 of 2]
Final Diagnosis:

A-C. Brain, left frontal mass #1-#3 and , resection: Low grade oligoastrocytoma, oligodendroglial predominant (WHO grade II).

Immunohistochemical stains were performed on paraffin embedded tissue using antibodies to GFAP, IDH1-R132H, p53 protein and Ki-67. GFAP is largely positive in background reactive astrocytes and focally in neoplastic cells with many gemistocytic morphology. Mutant IDH1 (IDH1-R132H) stain is positive consistent with IDH1 mutation. p53 protein is variably expressed in a moderate number of tumor cells. Ki-67 labeling index is low to focally moderate (up to 3-5%). The findings support the above diagnosis.

Fluorescence in situ hybridization (FISH) studies for 1p19q deletion have been ordered on paraffin sections and will be performed by the . For interpretation, see Synthesis in Labs under Genetics

Interpreted by:

Report electronically signed or

Transcribed by:

AMENDMENTS: (Previous Signout Date

Revision Description: In second paragraph, deletion of the beginning of the second to last sentence, "The find is low".

....Original Diagnosis....

A-C. Brain, left frontal mass #1-#3 and resection: Low grade oligoastrocytoma, oligodendroglial

continued next page Page 1 of 3

ICD-O-3

Oligoastrocytoma 9882/3

Site ^{path} ① Brain, frontal lobe

CLCF C71.1

Brain, supratentorial NOS C71.0

grw 5/10/13

[page 2 of 2]
predominant (WHO grade II).

Immunohistochemical stains were performed on paraffin embedded tissue using antibodies to GFAP, IDH1-R132H, p53 protein and Ki-67. GFAP is largely positive in background reactive astrocytes and focally in neoplastic cells with many gemistocytic morphology. Mutant IDH1 (IDH1-R132H) stain is positive consistent with IDH1 mutation. p53 protein is variably expressed in a moderate number of tumor cells. Ki-67 labeling index is low. The find is low to focally moderate (up to 3-5%). The findings support the above diagnosis.

Fluorescence in situ hybridization (FISH) studies for 1p19q deletion have been ordered on paraffin sections and will be performed by the . For interpretation, see Synthesis in Labs under Genetics

Signing Pathologist

Preliminary Frozen Section Consultation:

A. Brain, left frontal mass #1, smears: Positive for neoplasm. High-grade glioma. Hold over to confirm.

Intraoperative cytologic smear(s) interpretation performed by

Gross Description:

A. Received fresh labeled "left frontal brain mass" is a 9.0 x 3.3 x 2.5 cm portion of brain. Smears prepared. Representative sections are submitted. Grossed by

B. Received fresh labeled "left frontal brain mass #2" is a 5.0 x 2.5 x 1.8 cm aggregate of brain tissue. Representative sections are submitted for permanent sections only. Grossed by

C. Received fresh within a trap labeled ' specimen trap - left frontal brain mass" is a 5.0 x 4.0 x 1.3 cm aggregate of red-tan tissue. Representative sections are submitted for permanent sections only. Grossed by

Block Summary:

Part A: Left frontal brain mass

- 1 Lt frontal brain mass 1
- 2 Lt frontal brain mass 2
- 3 Lt frontal brain mass 3
- 4 Lt frontal brain mass 4
- 5 Lt frontal brain mass 5
- 6 Lt frontal brain mass 6

Part B: # 2 Left frontal brain mass

- 1 Lt frontal brain mass #2-1
- 2 Lt frontal brain mass #2-2
- 3 Lt frontal brain mass #2-3
- 4 Lt frontal brain mass #2-4
- 5 Lt frontal brain mass #2-5

Part C: specimen trap- left frontal brain mass

- 1 Lt frontal brain mass 1
- 2 Lt frontal brain mass 2

continued next page Page 2 of 3

4/2/13

Source: NCI Genomic Data Commons file 1811d329-1654-4e32-a839-17ccfb19a9bd (TCGA-DB-A64Q.1650DAE4-352B-4BDD-A48E-109FDE2CD3F9.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).